Surgical pathology report (de-identified scan), TCGA case TCGA-2Z-A9J2, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Z-A9J2-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Gender: F
Reported:
Submitting Physician:
Pathologist:
Internist Pathologist:
Performing Physician:

Service:

Received:

CLINICAL HISTORY:
7-YEAR-OLD FEMALE.

PREOPERATIVE DIAGNOSIS:
LEFT RENAL MASS.

SPECIMEN TYPE(S):
A: LEFT PERINEPHRIC FAT
B: LEFT KIDNEY
C: LEFT 12TH RIB

FINAL DIAGNOSIS:

- A. LEFT PERINEPHRIC FAT:
Fibroadipose tissue, negative for malignancy.
- B. LEFT KIDNEY, NEPHRECTOMY:
Papillary renal cell carcinoma, type 2, (see Key Pathological Findings and comment).

COMMENT: Immunohistochemical stains with adequate controls were performed on block, labeled B1 to further investigate this case. The neoplastic cells show immunoreactivity with vimentin, AMACR, CD10, and cadherin. They are negative with C-kit.

- C. LEFT 12TH RIB:
A portion of bone, consistent with a segment of rib (gross diagnosis).

KEY PATHOLOGICAL FINDINGS:

Specimen:	Left Kidney
Tumor type:	Papillary renal cell carcinoma, type 2.
Nuclear grade:	Grade 1.
Pattern of growth:	Solid.
Tumor size:	3 cm.
Renal capsule invasion:	Not identified.
Invasion of Gerota's fascia:	Not identified.
Renal vein invasion:	Not present.
Surgical margins:	Negative for malignancy.
Non-neoplastic kidney:	Focal mild chronic pyelonephritis.
Adrenal gland:	Not applicable.
Lymph nodes:	Not applicable.
Pathologic stage:	T1a NX MX

I, _____, M.D. the attending pathologist, personally reviewed the entire pathology case and rendered the final diagnosis. Electronically signed out by

OTHER RELATED CLINICAL DATA:

ICD O-3
Carcinoma, papillary renal cell
Site: ② Kidney NOS
8260/3
C64.9
JW 4/28/14

[page 2 of 2]
GROSS DESCRIPTION:

A. Specimen is received fresh, labeled "perinephric fat" and consists of a 7.0 x 3.5 x 1.5 cm, soft, yellow-tan, lobulated little fragment of adipose tissue. No palpable nodules are grossly appreciated. Cut surface is grossly unremarkable. Representative sections are submitted. A1 through A3.

B. Specimen B is labeled "left kidney". This specimen is received fresh and consists of a kidney which has a minimal amount of attached perinephric adipose tissue. The specimen weighs 90.9 grams and measures 10.0 x 4.5 x 4.0 cm. The capsule of the kidney is intact, and marked with black ink. Attached to the kidney is a 6.0 cm length of ureter, which upon opening grossly appears unremarkable. The specimen is bisected and revealed an ill-defined, firm, gray-yellow mass which is located in the inferior pole of the specimen measuring 3.0 x 2.5 x 1.5 cm. Grossly the mass does not appear to involve the renal capsule or renal perinephric adipose tissue. The renal pelvis and collecting system grossly appears free of tumor. The renal artery and vein are identified, opened and grossly are free of tumor. The remainder of the renal parenchyma is grossly unremarkable. No adrenal glands are attached to the specimen. On sectioning the isle of perinephric adipose tissue, no lymph nodes are isolated. Additional sectioning of the tumor reveals some calcification and fat necrosis (approximately 40%). A representative section of the mass is submitted to the Tissue Procurement Laboratory. Representative firm sections are submitted as: B1: Ureter and vessels. B2-B5: Tumor shown in relationship to adjacent tissue.

B6: Renal pelvis.
B7: Grossly unremarkable renal parenchyma.

C. Specimen C is labeled "portion of left 12th rib". The specimen is received fresh and consists of resected portion of bone which is grossly consistent with a segment of rib measuring 5.0 x 1.5 x 0.5 cm. The specimen grossly appeared unremarkable. No sections are submitted, gross only.

Source: NCI Genomic Data Commons file 6bef50d1-609d-484c-8923-3d208b8686b6 (TCGA-2Z-A9J2.2CBB70B5-A5D3-4385-9E05-5DD19243E127.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).